CPTAC case C3L-07988 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bbb37a44-af4c-4199-b623-0d4950c0ba88

Demographics
Sex at birth: female; Race: white; Year of birth: 1949; Vital status: Dead; Days to death: 236 days; Year of death: 2022; Cause of death: Cancer Related; Country of birth: Bulgaria.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Age at diagnosis: 72.1 years (26,317 days); Year of diagnosis: 2021; AJCC staging edition: 8th; AJCC clinical M: M1; AJCC pathologic T: T3; AJCC pathologic N: N3a; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Tumor grade: G3; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 236 days; Progression or recurrence: no; Days to last follow up: 201 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 15 cm; Lymph node involvement: Positive; Lymph nodes positive: 7; Lymph nodes tested: 7.

Follow-up (1 entry)
- Days to follow up: 201 days; Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-07988-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -14 days; Initial weight: 180 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-07988-23: Section location: Whole stomach; Percent tumor nuclei: 50; Percent necrosis: 0.
- Sample C3L-07988-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -14 days; Method of sample procurement: Blood Draw.
